Somatic mutation profile of tumor specimen TCGA-HC-7820-01A (aliquot TCGA-HC-7820-01A-11D-2114-08) from TCGA case TCGA-HC-7820, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 72.8 years (26,576 days).
Specimen TCGA-HC-7820-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a7e3a33-f1a4-45a2-a5f3-902212364a50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7820-10A (Blood Derived Normal), aliquot TCGA-HC-7820-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f93e4546-d65e-4f23-a33c-eda86d3f0233

The open-access MAF lists 31 somatic variants for this specimen: 28 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Nonsense Mutation 3, 5'UTR 2, Frame Shift Del 2, In Frame Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAD2 | c.970G>A p.G324R (on ENST00000315906 / NM_001145400.2; = p.G406R on NM_139174.4) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs201035894, COSV51893459; called by muse, mutect2, varscan2
- ALPP | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV67396340; called by muse, mutect2, varscan2
- ARIH2 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 16/194 reads (8%) | catalogued as rs554254556, COSV62704794; called by muse, mutect2
- CD38 | c.566G>A p.W189* | Nonsense Mutation (SNP) | VAF 32/96 reads (33%) | catalogued as COSV56890375; called by muse, mutect2, varscan2
- CDH5 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.208); catalogued as COSV58517541; called by muse, varscan2
- CPA5 | c.263A>G p.E88G | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1554403504, COSV62569636; called by muse, mutect2
- CYP2S1 | c.619G>C p.G207R | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.884); catalogued as COSV59506139; called by muse, mutect2
- DTX1 | c.1526A>G p.Y509C | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55656089; called by muse, mutect2, varscan2
- EIF2AK3 | c.2816A>G p.K939R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57547747; called by muse, mutect2, varscan2
- FAM174B | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs769884887, COSV59264176; called by muse, mutect2, varscan2
- FLI1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55642384; called by muse, mutect2
- KAT6B | c.1648A>T p.I550F | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.598); catalogued as COSV54746934; called by muse, mutect2, varscan2
- LILRB5 | c.1007C>G p.S336* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100300535; called by muse, mutect2
- LRRTM1 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV54439053; called by muse, mutect2, varscan2
- MACF1 | c.16135G>C p.V5379L (on ENST00000372915; = p.V3312L on NM_012090.5) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | catalogued as COSV57121528; called by muse, mutect2, varscan2
- MYH9 | c.5089C>T p.R1697C | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs372871106; called by muse, mutect2, varscan2
- NLGN1 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.014); catalogued as rs770240589, COSV64330956, COSV64337747; called by muse, mutect2, varscan2
- NLRP10 | c.1128G>T p.E376D | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV60780314; called by muse, mutect2, varscan2
- OPA1 | c.1395G>A p.M465I (on ENST00000361510 / NM_130837.3; = p.M410I on NM_015560.3) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV62480691; called by muse, mutect2, varscan2
- PLEKHA4 | c.328G>T p.G110W | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54363151; called by muse, mutect2
- PRKDC | c.8731C>A p.R2911S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV58052490, COSV58061277; called by muse, mutect2, varscan2
- RYR2 | c.3823G>A p.G1275S | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs769294223, COSV63657293, COSV63684336; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYCP1 | c.2296C>A p.Q766K | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV65697522; called by muse, mutect2, varscan2
- TEP1 | c.2668C>T p.P890S | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs552770900, COSV52992700; called by muse, mutect2, varscan2
- TSBP1 | c.1453_1455del p.K485del (on ENST00000617061; = p.K490del on NM_006781.5) | In Frame Del (DEL) | VAF 20/106 reads (19%) | catalogued as rs757525050; called by pindel, varscan2
- VRTN | c.2015A>T p.K672M | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56441103; called by muse, mutect2, varscan2
- CDH5 | c.588del p.E198Sfs*14 | Frame Shift Del (DEL) | VAF 22/172 reads (13%) | called by pindel, varscan2
- CLCNKB | c.687_688del p.H230Lfs*51 | Frame Shift Del (DEL) | VAF 21/143 reads (15%) | called by mutect2, pindel, varscan2
- SIPA1L3 | c.4176G>A p.A1392= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs572759177, COSV55914377, COSV55914825; called by muse, mutect2, varscan2
- PDPN | c.-110del | 5'UTR (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- PDPN | c.-115C>A | 5'UTR (SNP) | VAF 6/46 reads (13%) | catalogued as rs149456565, COSV53849001; called by mutect2, varscan2
